Gene-level copy-number profile of tumor specimen TCGA-C5-A8YQ-01A from TCGA case TCGA-C5-A8YQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 79.0 years (28,873 days).
Specimen TCGA-C5-A8YQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.c085861c-602a-4bf0-8b99-56df4e7b260f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A8YQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/916492be-477b-4f29-b602-f5faa825ac6a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,039; copy number 2: 20,592; copy number 3: 24,293; copy number 4: 7,653; copy number 5: 4,144; copy number 6: 712; copy number 7: 581; copy number 8: 38; copy number 9: 628; copy number 11: 28; copy number 13: 19; copy number 16: 79; copy number 65: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A8YQ-01A-11D-A37M-01): tumor purity 0.8, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,385 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:57,544,535–64,863,626, 136 genes, copy number 11–65 (within-gene range 9–65) (broad region; genes not listed).
- chr2:64,906,863–64,960,634, 2 genes, copy number 11: RN7SL211P, RPL11P1.
- chr3:139,005,806–139,357,223, 1 gene, copy number 8 (within-gene range 5–8): MRPS22.
- chr3:139,104,185–198,222,513, 1,029 genes, copy number 7–9 (broad region; genes not listed).
- chr7:18,807,993–18,899,433, 2 genes, copy number 8: RN7SKP266, HDAC9-AS1.
- chr7:54,752,250–62,275,678, 147 genes, copy number 7 (broad region; genes not listed).
- chr8:56,300,010–60,967,775, 68 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,039. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
